Somatic mutation profile of tumor specimen MMRF_2486_1_BM_CD138pos (aliquot MMRF_2486_1_BM_CD138pos_T1_KHS5U_K15189) from MMRF case MMRF_2486, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 34.9 years (12,764 days).
Specimen MMRF_2486_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c2e599b-2957-4169-9755-7618cea12c52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2486_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2486_1_PB_Whole_C2_KHS5U_K15190; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1d5e1e1-e35f-4905-81e2-25af201b52cd

The open-access MAF lists 85 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 26, Missense Mutation 20, Intron 13, Silent 9, 5'Flank 7, RNA 3, Frame Shift Ins 2, 3'Flank 2, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 65/146 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL15A1 | c.1159C>A p.L387I | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as COSV66648477; called by muse, mutect2, varscan2
- IGF1R | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV51284745; called by muse, mutect2, varscan2
- IGHG1 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as rs1188633154; called by muse, mutect2, varscan2
- IGHV2-70 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as rs369724963; called by muse, varscan2
- MAP3K4 | c.3610C>T p.R1204W | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs769365322, COSV62332172; called by muse, mutect2, varscan2
- PDZD2 | c.192dup p.E65Rfs*34 | Frame Shift Ins (INS) | VAF 80/330 reads (24%) | catalogued as rs755733994; called by mutect2, varscan2
- PRRG3 | c.494dup p.R166Qfs*14 | Frame Shift Ins (INS) | VAF 12/82 reads (15%) | catalogued as rs748526759; called by mutect2, varscan2
- RALGAPA2 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs1191999765; called by muse, mutect2, varscan2
- SPEG | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs376367804, COSV56667584; called by muse, mutect2, varscan2
- STIL | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.79); catalogued as COSV54547765; called by muse, mutect2, varscan2
- TBXA2R | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs377392586; called by muse, mutect2, varscan2
- XYLT1 | c.2362G>A p.V788I | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as rs201348549; called by muse, mutect2, varscan2
- ZAN | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.329); catalogued as rs1465710394, COSV100769699; called by muse, mutect2, varscan2
- BHLHA15 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DDX5 | c.1396_1399del p.A466Lfs*23 | Frame Shift Del (DEL) | VAF 65/168 reads (39%) | called by mutect2, pindel, varscan2
- IGLV3-1 | c.29T>G p.V10G | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IL17RA | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- KLF11 | c.1403A>C p.H468P | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYL1 | c.677C>A p.P226Q | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.415); called by muse, mutect2
- MEX3D | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NTRK3 | c.276C>G p.H92Q | Missense Mutation (SNP) | VAF 108/505 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYN1 | c.10C>A p.L4M | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC7 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- BCL11B | c.2265G>A p.P755= (on ENST00000357195 / NM_001282237.2; = p.P684= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs1397348808; called by muse, mutect2, varscan2
- FFAR1 | c.606C>T p.Y202= | Silent (SNP) | VAF 68/207 reads (33%) | catalogued as rs1441471324; called by muse, mutect2, varscan2
- FMN2 | c.864G>A p.R288= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1458996966; called by muse, mutect2
- HSPG2 | c.3756C>T p.G1252= | Silent (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- HUWE1 | c.2724T>C p.H908= | Silent (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- IGHJ3 | c.49G>A p.*17= | Silent (SNP) | VAF 46/47 reads (98%) | catalogued as rs368175492; called by muse, mutect2, varscan2
- KIF19 | c.1260A>G p.G420= | Silent (SNP) | VAF 28/43 reads (65%) | called by muse, mutect2, varscan2
- TMPRSS13 | c.834C>T p.A278= | Silent (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- TUBE1 | c.798C>T p.L266= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs782713361; called by muse, mutect2, varscan2
- A1CF | c.*21G>A | 3'UTR (SNP) | VAF 37/80 reads (46%) | catalogued as rs1246193584, COSV50975793; called by muse, mutect2, varscan2
- ADH5 | c.825+134dup | Intron (INS) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- AKT1 | c.702+14C>A | Intron (SNP) | VAF 24/55 reads (44%) | called by muse, varscan2
- ARHGEF17 | c.*1448C>T | 3'UTR (SNP) | VAF 4/13 reads (31%) | catalogued as rs886850018; called by muse, mutect2, varscan2
- BCL7A | chr12:122021002 G>A | 5'Flank (SNP) | VAF 66/152 reads (43%) | catalogued as rs1300922737, COSV55848702; called by muse, mutect2, varscan2
- BCL7A | chr12:122021485 C>T | 5'Flank (SNP) | VAF 95/201 reads (47%) | catalogued as COSV55848041; called by muse, mutect2, varscan2
- BCL7A | chr12:122021663 T>C | 5'Flank (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- C14orf132 | c.*6299T>C | 3'UTR (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- CACNB4 | c.*895C>T | 3'UTR (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- CDH5 | c.*76C>T | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- CORO1C | c.*347T>A | 3'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- CREB5 | c.*2966C>A | 3'UTR (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- CSMD2 | c.3287-240C>T | Intron (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- DLAT | c.*1299T>C | 3'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- DUT | chr15:48331183 C>T | 5'Flank (SNP) | VAF 80/156 reads (51%) | called by muse, mutect2, varscan2
- F11 | c.1135+1370C>T | Intron (SNP) | VAF 164/322 reads (51%) | catalogued as rs1036174042; called by muse, mutect2, varscan2
- FAT3 | c.*460A>C | 3'UTR (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- FMR1 | c.271-55T>G | Intron (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- GPAM | c.*3572C>T | 3'UTR (SNP) | VAF 60/123 reads (49%) | catalogued as rs533484707; called by muse, mutect2, varscan2
- HYDIN | c.382-115T>G | Intron (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- IGHV1-12 | n.67C>T | RNA (SNP) | VAF 53/123 reads (43%) | called by muse, mutect2, varscan2
- ITGA2 | c.*572A>T | 3'UTR (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- KALRN | c.*725dup | 3'UTR (INS) | VAF 41/120 reads (34%) | called by mutect2, pindel, varscan2
- KCNT1 | chr9:135792967 C>A | 3'Flank (SNP) | VAF 68/213 reads (32%) | called by muse, mutect2, varscan2
- LAPTM5 | c.*1322G>C | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- LGR4 | c.*1740del | 3'UTR (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- LRRC27 | c.*24G>A | 3'UTR (SNP) | VAF 64/171 reads (37%) | catalogued as COSV100889766; called by muse, mutect2, varscan2
- MIR124-2HG | n.209T>A | RNA (SNP) | VAF 147/333 reads (44%) | catalogued as rs986659747; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851253 A>G | 5'Flank (SNP) | VAF 89/181 reads (49%) | catalogued as rs762713616; called by muse, mutect2, varscan2
- MPC2 | c.*203T>A | 3'UTR (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- NCBP1 | c.*2258T>G | 3'UTR (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- NFIA | c.*6689A>C | 3'UTR (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2
- NHLH2 | chr1:115842509 G>A | 5'Flank (SNP) | VAF 66/171 reads (39%) | catalogued as rs1272399109; called by muse, mutect2
- NR2F2 | c.*2263G>T | 3'UTR (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- PI4KB | c.2269+36C>T | Intron (SNP) | VAF 35/288 reads (12%) | called by muse, mutect2, varscan2
- PML | c.*879A>G | 3'UTR (SNP) | VAF 76/154 reads (49%) | called by muse, mutect2, varscan2
- PRKAG1 | c.9+1175G>A | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- PTPN20 | chr10:47001421 T>G | 3'Flank (SNP) | VAF 173/393 reads (44%) | called by muse, mutect2, varscan2
- RSPH4A | c.-133C>T | 5'UTR (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- SKIL | c.*1059G>A | 3'UTR (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- SLC41A3 | c.274-5671C>T | Intron (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- SOGA1 | c.*315C>G | 3'UTR (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- SPAG6 | c.1460+1307G>C | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- SSPOP | n.4218G>C | RNA (SNP) | VAF 82/204 reads (40%) | called by muse, mutect2, varscan2
- TENT5C | c.*2019C>A | 3'UTR (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- TICRR | c.*733C>A | 3'UTR (SNP) | VAF 69/229 reads (30%) | called by muse, mutect2, varscan2
- TNMD | c.181-150G>T | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- TNRC6A | c.*348T>C | 3'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.*6201A>G | 3'UTR (SNP) | VAF 11/56 reads (20%) | catalogued as rs9917; called by muse, mutect2, varscan2
- ZFP28 | c.898+193C>A | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- ZNF774 | chr15:90349217 G>A | 5'Flank (SNP) | VAF 19/603 reads (3%) | catalogued as rs982547100; called by muse, mutect2
- ZNF780B | c.232+79T>A | Intron (SNP) | VAF 8/25 reads (32%) | catalogued as rs1390790519; called by muse, mutect2, varscan2
